MMRF case MMRF_1079 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/abe15e81-998d-4b64-9776-b884fa763d13

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; ISS stage: I; Days to last known disease status: 1,793 days (4.9 years); Days to last follow up: 1,793 days (4.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 40 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 75 days; Days to treatment end: 75 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 99 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 226 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 227 days; Days to treatment end: 227 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,331 days (3.6 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,597 days (4.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 1.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.13 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0.65 mg/dL.
- Day 75 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 6.43 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.73 µg/mL; Lactate Dehydrogenase 8.8 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.07 mmol/L.
- Day 187 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.631 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 4.68 mmol/L.
- Day 255 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 4.6 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 3.93 µg/mL; Lactate Dehydrogenase 4.6 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 5.12 mmol/L.
- Day 352 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Immunoglobulin G 8.35 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 3.47 mmol/L.
- Day 506 (ECOG 0): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.78 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 3.85 mmol/L.
- Day 604 (ECOG 0): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 4.86 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.13 mmol/L.
- Day 695 (ECOG 0): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 786 (ECOG 1): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 5.63 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.
- Day 877 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.92 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 4.51 mmol/L.
- Day 967 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.29 mg/dL; Immunoglobulin G 5.54 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 4.13 mmol/L.
- Day 1,059 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 6.03 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 7.21 mmol/L.
- Day 1,138 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 6.29 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 2.76 µg/mL; Hemoglobin 9.36 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.18 mmol/L.
- Day 1,237 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.4 mmol/L.
- Day 1,346 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 7.49 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 3.16 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 9.1 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.02 mmol/L.
- Day 1,443 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 6.47 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 33 g/L; Total Protein 5.8 g/dL; Glucose 4.29 mmol/L.
- Day 1,529 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.249 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.236 mg/dL; Immunoglobulin G 5.63 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 3.26 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 4.68 mmol/L.
- Day 1,626 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.731 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.927 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 160 ×10⁹/L.
- Day 1,709 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.25 mg/dL; Immunoglobulin G 3.8 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 3.42 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 7.37 mmol/L.
- Day 1,793 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 10.6 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.03 mmol/L; Albumin 28 g/L; Total Protein 5.5 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -6: Weight: 72 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Melanoma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (3 samples)
- Sample MMRF_1079_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1079_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,346 days (3.7 years).
- Sample MMRF_1079_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1,346 days (3.7 years).
